Somatic mutation profile of tumor specimen TCGA-B0-5690-01A (aliquot TCGA-B0-5690-01A-11D-1534-10) from TCGA case TCGA-B0-5690, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 53.9 years (19,685 days).
Specimen TCGA-B0-5690-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 441e7043-c384-4904-9c04-282f92a495e1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-5690-11A (Solid Tissue Normal), aliquot TCGA-B0-5690-11A-01D-1534-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9e11c7fe-1e38-4f09-b26f-4a7c54ca8720

The open-access MAF lists 65 somatic variants for this specimen: 51 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 13, Splice Site 4, Splice Region 2, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA10 | c.4487C>A p.T1496N | Missense Mutation (SNP) | VAF 57/318 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99288861; called by muse, mutect2, varscan2
- ARHGAP4 | c.1781C>A p.P594H | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs372676050, COSV100509567; called by muse, mutect2
- ARHGEF25 | c.978G>A p.M326I | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as COSV99678096; called by muse, mutect2, varscan2
- ARSF | c.1369C>T p.R457W | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753503000, COSV100839538; called by mutect2, varscan2
- BRD7 | c.1370A>G p.Y457C | Missense Mutation (SNP) | VAF 68/339 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); catalogued as rs569809930, COSV67158292, COSV67160314; called by muse, mutect2, varscan2
- CDX4 | c.119C>T p.P40L | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100999141, COSV65171674; called by muse, mutect2, varscan2
- CENPF | c.1790C>T p.A597V | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.844); catalogued as COSV100871759; called by muse, mutect2, varscan2
- CHRM2 | c.291C>G p.D97E | Missense Mutation (SNP) | VAF 57/253 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100281563; called by muse, mutect2, varscan2
- CS | c.1216G>A p.G406R | Missense Mutation (SNP) | VAF 10/279 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100369987; called by muse, mutect2
- CXCR4 | c.808A>G p.I270V | Missense Mutation (SNP) | VAF 43/168 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.059); catalogued as COSV99603138; called by muse, mutect2, varscan2
- DCTN2 | c.658C>A p.Q220K (on ENST00000548249 / NM_001261413.2; = p.Q225K on NM_006400.4) | Missense Mutation (SNP) | VAF 52/214 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.192); catalogued as COSV100851708; called by muse, mutect2, varscan2
- EPN2 | c.899G>A p.G300D | Missense Mutation (SNP) | VAF 50/284 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs773633651, COSV100127653; called by muse, mutect2, varscan2
- GFI1B | c.244C>T p.P82S | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs760373604, COSV100254296; called by muse, mutect2, varscan2
- GTF2IRD2B | c.359G>T p.G120V | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV100441185; called by muse, mutect2, varscan2
- IRF4 | c.1210C>A p.H404N | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV101110902; called by muse, mutect2, varscan2
- ITPRID2 | c.2978T>G p.M993R | Missense Mutation (SNP) | VAF 36/174 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100238446; called by muse, mutect2, varscan2
- KCNN1 | c.730G>A p.V244M | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV99716107; called by muse, mutect2, varscan2
- LILRA2 | c.214C>T p.R72W | Missense Mutation (SNP) | VAF 32/172 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs764683666, COSV99253321; called by muse, mutect2, varscan2
- LPA | c.1184C>T p.S395L | Missense Mutation (SNP) | VAF 24/202 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as rs758495741; called by muse, mutect2, varscan2
- LRP2 | c.8909G>T p.W2970L | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99789259; called by muse, mutect2, varscan2
- MAFB | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.677); catalogued as rs201783302, COSV100965056; called by mutect2, varscan2
- MCF2 | c.1984C>T p.L662F | Missense Mutation (SNP) | VAF 15/457 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1556020010, COSV100644869, COSV58495308; called by muse, mutect2
- MEGF10 | c.1045C>G p.R349G | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.051); catalogued as COSV57245326, COSV99175084; called by muse, mutect2, varscan2
- NIN | c.981G>A p.K327= | Splice Region (SNP) | VAF 30/129 reads (23%) | catalogued as COSV99814056; called by muse, mutect2, varscan2
- NUP85 | c.1720T>C p.W574R | Missense Mutation (SNP) | VAF 32/165 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV99822143; called by muse, mutect2, varscan2
- P2RX1 | c.526C>A p.P176T | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1465339788, COSV56654296, COSV99844810; called by muse, mutect2, varscan2
- PACC1 | c.835C>G p.Q279E | Missense Mutation (SNP) | VAF 66/281 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.12); catalogued as COSV99801289; called by muse, mutect2, varscan2
- PBRM1 | c.4610-1G>T p.X1537_splice (on ENST00000296302 / NM_001366071.2; = p.X1430_splice on NM_018313.5) | Splice Site (SNP) | VAF 23/84 reads (27%) | catalogued as COSV56269170, COSV56275990, COSV56299222; called by muse, mutect2, varscan2
- PLIN4 | c.1570G>A p.G524R (on ENST00000301286; = p.G539R on NM_001367868.2) | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as rs374931763; called by muse, mutect2, varscan2
- POLR1A | c.1127G>A p.S376N | Missense Mutation (SNP) | VAF 84/394 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.07); catalogued as COSV99807968; called by muse, mutect2, varscan2
- PRPSAP2 | c.543G>T p.R181S | Missense Mutation (SNP) | VAF 61/242 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.15); catalogued as COSV52066969, COSV99264208; called by muse, mutect2, varscan2
- PRRC2B | c.1811G>A p.S604N | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV100621916; called by muse, mutect2, varscan2
- PTPN21 | c.1001C>A p.P334H | Missense Mutation (SNP) | VAF 90/376 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as rs369308133, COSV100162176; called by muse, mutect2, varscan2
- RAB34 | c.407A>C p.D136A | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as rs1189869733, COSV99972806; called by muse, mutect2, varscan2
- RFC2 | c.611A>G p.N204S (on ENST00000055077 / NM_181471.3; = p.N170S on NM_002914.4) | Missense Mutation (SNP) | VAF 35/143 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs941701937, COSV99277983; called by muse, mutect2, varscan2
- ROBO2 | c.1084C>A p.Q362K | Missense Mutation (SNP) | VAF 68/254 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV100167824; called by muse, mutect2, varscan2
- ROCK1 | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 130/570 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV101296478; called by muse, mutect2, varscan2
- SERINC2 | c.920T>C p.V307A (on ENST00000373709 / NM_178865.5; = p.V311A on NM_018565.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV101036983; called by muse, mutect2, varscan2
- SRFBP1 | c.1105+1G>A p.X369_splice | Splice Site (SNP) | VAF 104/403 reads (26%) | catalogued as rs753126669, COSV100232819; called by muse, mutect2, varscan2
- TICRR | c.3080C>T p.A1027V | Missense Mutation (SNP) | VAF 53/222 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.288); catalogued as rs777288885, COSV99176867; called by muse, mutect2, varscan2
- TMEM144 | c.338G>A p.G113D | Missense Mutation (SNP) | VAF 154/611 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99646880; called by muse, mutect2, varscan2
- TRA2B | c.152G>A p.R51K | Missense Mutation (SNP) | VAF 93/274 reads (34%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.035); catalogued as COSV99373292; called by muse, mutect2, varscan2
- UCMA | c.180G>C p.R60S | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.178); catalogued as COSV101095459; called by muse, varscan2
- WDFY3 | c.6075G>A p.G2025= | Splice Region (SNP) | VAF 26/122 reads (21%) | catalogued as COSV99884216; called by muse, mutect2, varscan2
- XPO7 | c.111T>A p.F37L | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT tolerated (0.96); PolyPhen benign (0.034); catalogued as COSV99381571; called by muse, mutect2, varscan2
- ZC3H3 | c.1388G>T p.G463V | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as COSV99368114; called by muse, mutect2, varscan2
- ZMIZ2 | c.814-1G>A p.X272_splice | Splice Site (SNP) | VAF 5/32 reads (16%) | catalogued as rs1263247298, COSV54806304; called by muse, mutect2, varscan2
- EPB41L2 | c.1522_1535del p.F508Vfs*6 | Frame Shift Del (DEL) | VAF 15/94 reads (16%) | called by mutect2, pindel
- IGKV1-16 | c.328T>G p.C110G | Missense Mutation (SNP) | VAF 58/322 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.537); called by muse, mutect2, varscan2
- LAMB1 | c.4245C>A p.N1415K | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SETD2 | c.7424_7431+8del p.X2475_splice | Splice Site (DEL) | VAF 148/694 reads (21%) | called by mutect2, pindel, varscan2
- ALK | c.2946G>A p.K982= | Silent (SNP) | VAF 62/215 reads (29%) | catalogued as COSV66581229; called by muse, mutect2, varscan2
- DHX9 | c.2565G>T p.L855= | Silent (SNP) | VAF 48/250 reads (19%) | catalogued as COSV100841463; called by muse, mutect2, varscan2
- DIP2A | c.3432C>T p.P1144= | Silent (SNP) | VAF 12/270 reads (4%) | catalogued as rs1277683206, COSV100596039; called by muse, mutect2
- EIF3A | c.3873C>T p.D1291= | Silent (SNP) | VAF 58/245 reads (24%) | catalogued as rs774454537, COSV64961656; called by muse, mutect2, varscan2
- IRAG1 | c.1713A>G p.K571= | Silent (SNP) | VAF 186/720 reads (26%) | catalogued as COSV101351339; called by muse, mutect2, varscan2
- KIF11 | c.774C>T p.I258= | Silent (SNP) | VAF 73/345 reads (21%) | catalogued as rs749542461, COSV99585945; called by muse, mutect2, varscan2
- NSD1 | c.54T>C p.N18= | Silent (SNP) | VAF 23/106 reads (22%) | catalogued as COSV100729512; called by muse, mutect2, varscan2
- PM20D1 | c.1035A>G p.A345= | Silent (SNP) | VAF 144/679 reads (21%) | catalogued as COSV100900213; called by muse, mutect2, varscan2
- PPARA | c.558A>T p.A186= | Silent (SNP) | VAF 69/250 reads (28%) | catalogued as COSV99415626; called by muse, mutect2, varscan2
- PPP2R1B | c.96C>A p.L32= | Silent (SNP) | VAF 28/102 reads (27%) | catalogued as COSV100232249; called by muse, mutect2, varscan2
- SLC16A4 | c.264T>C p.T88= | Silent (SNP) | VAF 64/290 reads (22%) | catalogued as COSV100872974; called by muse, mutect2, varscan2
- TBX22 | c.405G>T p.G135= | Silent (SNP) | VAF 14/404 reads (3%) | catalogued as COSV100960859; called by muse, mutect2
- WASHC2A | c.306A>G p.E102= | Silent (SNP) | VAF 28/1033 reads (3%) | called by muse, mutect2
- TTN | c.10360+3786del | Intron (DEL) | VAF 32/166 reads (19%) | called by mutect2, pindel, varscan2
